Somatic mutation profile of tumor specimen MP2PRT-PARHBJ-TMP1-B (aliquot MP2PRT-PARHBJ-TMP1-B-1-0-D-A834-36) from MP2PRT case MP2PRT-PARHBJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.2 years (1,165 days).
Specimen MP2PRT-PARHBJ-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f761df6-3bb9-4d7e-b146-09d3af711a4d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARHBJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARHBJ-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9af1f539-2157-4bbb-9378-466c547db36e

The open-access MAF lists 20 somatic variants for this specimen: 19 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 15, Frame Shift Del 2, Silent 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ETV6 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs724159945, CM150817, COSV56766387, COSV56766702, COSV56766787; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FZD7 | c.1585G>A p.V529I | Missense Mutation (SNP) | VAF 134/472 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.42); catalogued as COSV53810608; called by muse, varscan2
- SERINC5 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 83/236 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as rs1223898432; called by muse, mutect2, varscan2
- TRPC6 | c.1805C>A p.A602D | Missense Mutation (SNP) | VAF 51/229 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60256287; called by muse, mutect2, varscan2
- AFP | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- BRPF1 | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 76/435 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DEFB116 | c.179_180insAACCTGCCCAAATGATCAAAAGTGCTGCCTGAAACTT p.C61Tfs*16 | Frame Shift Ins (INS) | VAF 3/24 reads (13%) | called by mutect2*, pindel
- EPHA3 | c.1603A>G p.I535V | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2
- IGKV1D-16 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 111/437 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- NCAPG | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2
- PELO | c.475A>C p.T159P | Missense Mutation (SNP) | VAF 33/406 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- SALL2 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 33/400 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2
- SPHKAP | c.1462_1474del p.S488Pfs*5 | Frame Shift Del (DEL) | VAF 4/45 reads (9%) | called by mutect2*, pindel
- TRIM49 | c.302A>C p.K101T | Missense Mutation (SNP) | VAF 34/326 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- UBA2 | c.74_75insTCCGGC p.A25_G26insPA | In Frame Ins (INS) | VAF 53/232 reads (23%) | called by pindel, varscan2
- UBAP2 | c.1451C>A p.P484H | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UBL5 | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.58); PolyPhen benign (0.022); called by muse, mutect2
- UPK3B | c.156_184del p.P53Rfs*84 | Frame Shift Del (DEL) | VAF 4/41 reads (10%) | called by mutect2*, pindel
- USP19 | c.2082C>A p.S694R | Missense Mutation (SNP) | VAF 23/251 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.129); called by muse, mutect2
- GLI2 | c.1773G>A p.P591= (on ENST00000361492 / NM_001374353.1; = p.P608= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/624 reads (14%) | catalogued as rs776509889, COSV100082070; called by muse, varscan2
